Gene-level copy-number profile of tumor specimen C3L-04911-01 from CPTAC case C3L-04911, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 83.9 years (30,659 days).
Specimen C3L-04911-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a2eee5c1-e998-4fbc-b9ca-6dccd6a2668c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04911-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/7a69658d-502f-440b-898b-1b2c60247e04

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 2,023; copy number 2: 32,245; copy number 3: 18,463; copy number 4: 4,155; copy number 5: 1,332; copy number 6: 104; copy number 7: 2; copy number 10: 33; copy number 133: 16.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:19,089,151–19,376,400, 6 genes (within-gene range 0–2): RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P.
- chr13:82,778,208–83,298,167, 4 genes: AL445255.1, GYG1P2, AL512782.1, RNU6-67P.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr22:18,715,815–18,947,741, 13 genes: PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,487 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:163,109,152–163,361,563, 1 gene, copy number 5 (within-gene range 4–5): LINC01192.
- chr3:163,455,568–178,385,479, 181 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:179,794,958–182,536,772, 48 genes, copy number 5: PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1, RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995.
- chr3:182,739,669–198,123,232, 364 genes, copy number 5 (broad region; genes not listed).
- chr6:6,938,606–8,760,447, 32 genes, copy number 5 (within-gene range 4–5): RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3.
- chr7:100,319,222–101,204,495, 61 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr10:120,608,580–121,928,492, 16 genes, copy number 133 (within-gene range 3–133): AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA.
- chr14:18,333,726–18,343,144, 2 genes, copy number 7: CR383658.1, RNU6-458P.
- chr18:14,337,423–14,393,909, 5 genes, copy number 5: CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2.
- chr18:22,347,846–23,260,467, 14 genes, copy number 5 (within-gene range 4–5): AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1.
- chr18:23,257,164–23,260,354, 1 gene, copy number 5 (within-gene range 4–5): AC011731.1.
- chr18:42,743,227–46,920,160, 47 genes, copy number 6–10 (within-gene range 1–10): RIT2, SYT4, AC022743.1, AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1.
- chr20:34,280,268–56,639,283, 511 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:57,895,394–64,327,972, 204 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,016. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
